Somatic mutation profile of tumor specimen TCGA-CJ-4639-01A (aliquot TCGA-CJ-4639-01A-02D-1386-10) from TCGA case TCGA-CJ-4639, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 49.5 years (18,066 days).
Specimen TCGA-CJ-4639-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 455b72d3-c6d8-4f84-b0ba-b4110b1429b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-4639-11A (Solid Tissue Normal), aliquot TCGA-CJ-4639-11A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbbf2403-b46a-446b-a280-af6e6b7b21e8

The open-access MAF lists 54 somatic variants for this specimen: 44 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 9, Frame Shift Ins 4, Frame Shift Del 3, Nonsense Mutation 2, Translation Start Site 1, 3'UTR 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTRT1 | c.347G>T p.R116M | Missense Mutation (SNP) | VAF 105/373 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.874); catalogued as rs1569354666, COSV64419744; called by muse, mutect2, varscan2
- ADCY9 | c.2319G>T p.K773N | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV53578585; called by muse, mutect2, varscan2
- AIFM1 | c.110A>C p.N37T | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs1353159825, COSV54856508; called by muse, mutect2, varscan2
- AKAP1 | c.1460G>A p.C487Y | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.545); catalogued as COSV58471578; called by muse, mutect2, varscan2
- APLP1 | c.656C>A p.S219Y | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.689); catalogued as rs142658251; called by muse, mutect2, varscan2
- ATAD5 | c.3329T>C p.I1110T | Missense Mutation (SNP) | VAF 69/282 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV58976717; called by muse, mutect2, varscan2
- ATM | c.385A>T p.K129* | Nonsense Mutation (SNP) | VAF 36/355 reads (10%) | catalogued as COSV53759082; called by muse, mutect2, varscan2
- ATM | c.8558C>G p.T2853R | Missense Mutation (SNP) | VAF 49/338 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141534716, CM157957, COSV53759103; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CENPH | c.730G>T p.V244F | Missense Mutation (SNP) | VAF 109/350 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV51585290; called by muse, mutect2, varscan2
- DISP3 | c.3425G>A p.R1142H | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs766972446, COSV53828363; called by muse, mutect2, varscan2
- GSK3A | c.1125G>T p.E375D | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as COSV55900153; called by muse, mutect2, varscan2
- HHIP | c.1861G>A p.G621R | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56841886; called by muse, mutect2, varscan2
- KANSL1 | c.1175G>C p.R392T | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.627); catalogued as COSV52271388; called by muse, mutect2, varscan2
- KLC3 | c.1394T>G p.M465R | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV67269272; called by muse, mutect2, varscan2
- LAP3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs139709924, COSV56900835; called by muse, varscan2
- MFHAS1 | c.2249A>G p.H750R | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs781129814, COSV52285207; called by muse, mutect2, varscan2
- MFSD6L | c.106C>T p.L36F | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61004406; called by muse, mutect2
- MMP17 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775074248, COSV62180402; called by muse, mutect2, varscan2
- MUC17 | c.13178G>A p.G4393D | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as rs779711446, COSV60296115; called by muse, mutect2
- NFATC1 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs767042185, COSV53697749; called by muse, mutect2, varscan2
- NLRP4 | c.1230C>A p.D410E | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV100017060, COSV56718704; called by muse, mutect2, varscan2
- NUCKS1 | c.145C>G p.R49G | Missense Mutation (SNP) | VAF 79/344 reads (23%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.969); catalogued as COSV63347876; called by muse, mutect2, varscan2
- POLG2 | c.548A>T p.E183V | Missense Mutation (SNP) | VAF 55/197 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV56750328; called by muse, mutect2, varscan2
- RBL2 | c.881A>C p.K294T | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50882617; called by muse, mutect2, varscan2
- RGS2 | c.589G>T p.D197Y | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV52459431; called by muse, mutect2, varscan2
- SEMA4G | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV52970050; called by muse, mutect2, varscan2
- STX4 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as rs373829816; called by muse, mutect2, varscan2
- TBL1X | c.1376C>A p.T459N | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV54284207; called by muse, mutect2, varscan2
- TPRG1L | c.810A>G p.I270M | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV54562383; called by muse, mutect2, varscan2
- UBR4 | c.10463A>C p.E3488A | Missense Mutation (SNP) | VAF 69/313 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as COSV64394584; called by muse, mutect2, varscan2
- USH2A | c.8915C>T p.S2972F | Missense Mutation (SNP) | VAF 56/221 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56387503, COSV56401661; called by muse, mutect2, varscan2
- VDR | c.83G>C p.G28A | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57469225; called by muse, mutect2, varscan2
- WDPCP | c.1935C>G p.D645E | Missense Mutation (SNP) | VAF 72/249 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV55426187; called by muse, mutect2, varscan2
- ZACN | c.544+1G>A p.X182_splice | Splice Site (SNP) | VAF 16/61 reads (26%) | catalogued as rs771834004, COSV58037124; called by muse, mutect2, varscan2
- ZNF106 | c.346A>T p.S116C | Missense Mutation (SNP) | VAF 94/363 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV55519136; called by muse, mutect2, varscan2
- COL3A1 | c.946del p.A316Lfs*94 | Frame Shift Del (DEL) | VAF 41/171 reads (24%) | called by mutect2, pindel, varscan2
- IL13RA1 | c.952_953dup p.L319Sfs*17 | Frame Shift Ins (INS) | VAF 27/143 reads (19%) | called by mutect2, pindel, varscan2
- KIAA1109 | c.12706del p.M4236Wfs*5 | Frame Shift Del (DEL) | VAF 48/203 reads (24%) | called by mutect2, pindel, varscan2
- MAP1B | c.750del p.S251Rfs*5 | Frame Shift Del (DEL) | VAF 36/197 reads (18%) | called by mutect2, pindel, varscan2
- SLC2A11 | c.1062dup p.F355Lfs*46 (on ENST00000345044 / NM_001024938.4; = p.F362Lfs*46 on NM_030807.5) | Frame Shift Ins (INS) | VAF 62/247 reads (25%) | called by mutect2, pindel, varscan2
- STAM | c.571_573del p.S191del | In Frame Del (DEL) | VAF 19/132 reads (14%) | called by mutect2, pindel, varscan2
- TAF4 | c.2875dup p.D959Gfs*2 | Frame Shift Ins (INS) | VAF 40/180 reads (22%) | called by mutect2, pindel, varscan2
- TMEM144 | c.262dup p.T88Nfs*15 | Frame Shift Ins (INS) | VAF 108/379 reads (28%) | called by mutect2, pindel, varscan2
- TRBC2 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 29/102 reads (28%) | called by muse, mutect2, varscan2
- ARFIP2 | c.534T>A p.L178= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV54447747; called by muse, mutect2, varscan2
- DISP3 | c.3426C>T p.R1142= | Silent (SNP) | VAF 47/147 reads (32%) | catalogued as COSV53832908; called by muse, mutect2, varscan2
- GOT2 | c.939T>G p.R313= | Silent (SNP) | VAF 77/363 reads (21%) | catalogued as COSV55332368; called by muse, mutect2, varscan2
- OLFML2B | c.1419C>A p.T473= | Silent (SNP) | VAF 10/204 reads (5%) | catalogued as COSV99668405; called by muse, mutect2
- PFKFB3 | c.252C>T p.S84= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as COSV57991089; called by muse, mutect2, varscan2
- POU2F1 | c.942G>A p.G314= (on ENST00000541643 / NM_001365848.1; = p.G337= on NM_002697.4) | Silent (SNP) | VAF 81/316 reads (26%) | catalogued as COSV54821058; called by muse, mutect2, varscan2
- SNX18 | c.1608C>T p.I536= | Silent (SNP) | VAF 48/193 reads (25%) | catalogued as COSV57990845; called by muse, mutect2, varscan2
- SPOCK1 | c.423G>T p.V141= | Silent (SNP) | VAF 25/240 reads (10%) | catalogued as COSV56457144; called by muse, mutect2, varscan2
- TRIM42 | c.963C>T p.H321= | Silent (SNP) | VAF 75/265 reads (28%) | catalogued as rs973883247, COSV53880614; called by muse, mutect2, varscan2
- SLC17A2 | c.*140T>G | 3'UTR (SNP) | VAF 57/235 reads (24%) | catalogued as COSV55353801; called by muse, mutect2, varscan2
